Somatic mutation profile of tumor specimen C3L-03356-02 (aliquot CPT0198420007) from CPTAC case C3L-03356, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 71.5 years (26,098 days).
Specimen C3L-03356-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc378124-75d3-4fb7-9a1a-f0ddd7593a39.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03356-31 (Blood Derived Normal), aliquot CPT0198450002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/887da4bc-95da-4bb0-a17f-e6d49f2a1d0f

The open-access MAF lists 31 somatic variants for this specimen: 21 protein-altering or splice-affecting, 4 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 4, Intron 3, Nonsense Mutation 2, RNA 1, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 50/586 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- TP53 | c.388C>G p.L130V | Missense Mutation (SNP) | VAF 52/582 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs863224683, CM016206, COSV52686543, COSV52692226, COSV99368721; ClinVar: uncertain significance; called by muse, mutect2
- CACNA2D1 | c.102A>T p.K34N | Missense Mutation (SNP) | VAF 46/692 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.056); catalogued as COSV62388142; called by muse, mutect2
- FGD1 | c.1913G>A p.R638H | Missense Mutation (SNP) | VAF 62/423 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1379096006; called by muse, mutect2, varscan2
- GRIK2 | c.1066G>A p.G356R | Missense Mutation (SNP) | VAF 28/458 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59736816; called by muse, mutect2
- HEMGN | c.1208C>T p.P403L | Missense Mutation (SNP) | VAF 80/1120 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as rs777811108; called by muse, mutect2
- LOX | c.316A>C p.T106P | Missense Mutation (SNP) | VAF 39/532 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs575026013, COSV50239708; called by muse, mutect2
- OR1M1 | c.829A>T p.M277L | Missense Mutation (SNP) | VAF 44/660 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.881); catalogued as rs1269516060; called by muse, mutect2
- OR2W1 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 17/300 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs896592244, COSV65851468; called by muse, mutect2
- PCLO | c.15151G>C p.V5051L | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61653484; called by muse, mutect2
- PCNT | c.2524G>C p.E842Q | Missense Mutation (SNP) | VAF 30/216 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV64025049, COSV64025882, COSV64029451; called by muse, mutect2, varscan2
- SLC4A11 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 44/717 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs771135532, COSV66261411; called by muse, mutect2
- C1QTNF2 | c.232C>T p.Q78* (on ENST00000393975; = p.Q33* on NM_031908.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 38/450 reads (8%) | called by muse, mutect2
- COL9A2 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 46/645 reads (7%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2
- DNAH9 | c.4350G>T p.Q1450H | Missense Mutation (SNP) | VAF 68/816 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2
- ITLN1 | c.746C>A p.A249D | Missense Mutation (SNP) | VAF 27/521 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- NFIX | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 104/1364 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- OTOG | c.1732C>T p.P578S | Missense Mutation (SNP) | VAF 47/756 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); called by muse, mutect2
- TBC1D32 | c.1613C>T p.S538F | Missense Mutation (SNP) | VAF 36/424 reads (8%) | SIFT tolerated (0.66); PolyPhen benign (0.006); called by muse, mutect2
- TGFBR2 | c.190C>T p.Q64* | Nonsense Mutation (SNP) | VAF 38/516 reads (7%) | called by muse, mutect2
- ZNF181 | c.816G>C p.K272N | Missense Mutation (SNP) | VAF 32/594 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); called by muse, mutect2
- DNAH17 | c.7980C>T p.S2660= | Silent (SNP) | VAF 20/314 reads (6%) | catalogued as rs574957481, COSV101102934; called by muse, mutect2
- SLC25A47 | c.723C>A p.I241= | Silent (SNP) | VAF 50/652 reads (8%) | catalogued as COSV59925049; called by muse, mutect2
- TMEM241 | c.387C>A p.A129= | Silent (SNP) | VAF 21/338 reads (6%) | called by muse, mutect2
- ZNF724 | c.1839T>A p.A613= | Silent (SNP) | VAF 19/242 reads (8%) | called by muse, mutect2
- BAALC-AS2 | n.350T>C | RNA (SNP) | VAF 68/844 reads (8%) | called by muse, mutect2
- ERBB2 | chr17:39699571 G>A | 5'Flank (SNP) | VAF 14/344 reads (4%) | called by muse, mutect2
- FBRSL1 | c.645+3303T>G | Intron (SNP) | VAF 19/237 reads (8%) | called by muse, mutect2
- IL17RC | c.1735+41G>C | Intron (SNP) | VAF 200/461 reads (43%) | called by muse, mutect2, varscan2
- LRRC6 | c.10+21C>T | Intron (SNP) | VAF 6/117 reads (5%) | called by muse, mutect2
- TUBG1 | c.-16C>T | 5'UTR (SNP) | VAF 18/274 reads (7%) | catalogued as rs998269947; ClinVar: likely benign; called by muse, mutect2
